Somatic mutation profile of tumor specimen MP2PRT-PAUYIT-TMP1-A (aliquot MP2PRT-PAUYIT-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAUYIT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,038 days).
Specimen MP2PRT-PAUYIT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11628e85-a222-465a-888e-88a8b9407c3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUYIT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUYIT-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4047c459-f5f8-49b6-bb58-0415b637b667

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NAV2 | c.1549C>T p.R517W (on ENST00000396087 / NM_001244963.2; = p.R494W on NM_145117.5) | Missense Mutation (SNP) | VAF 28/412 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.803); catalogued as rs754191884, COSV100587557; called by muse, mutect2
- NCBP2 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 151/359 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.102); catalogued as rs1309778781, COSV58317145; called by muse, mutect2, varscan2
- SYNE1 | c.16025C>T p.T5342M (on ENST00000367255 / NM_182961.4; = p.T5271M on NM_033071.3) | Missense Mutation (SNP) | VAF 103/446 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs202105931; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- ATP9A | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 137/286 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C6orf132 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 147/548 reads (27%) | SIFT tolerated, low confidence (0.21); called by muse, mutect2, varscan2
- COL11A1 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 9/177 reads (5%) | called by muse, mutect2
- IGKV1OR2-108 | chr2:113406853 CAGGATTATACTACCCCATTCACA>AGG | Missense Mutation (DEL) | VAF 65/221 reads (29%) | called by pindel, varscan2*
- KMT2A | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 119/312 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- MAPK4 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 32/854 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); called by muse, mutect2
- PKHD1 | c.6368G>A p.G2123E | Missense Mutation (SNP) | VAF 90/316 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PXN | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 124/348 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SRRM3 | c.297G>T p.E99D | Missense Mutation (SNP) | VAF 123/362 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TPST2 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 24/540 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2
- ASIC2 | c.534C>T p.C178= | Silent (SNP) | VAF 76/315 reads (24%) | catalogued as rs369406106; called by muse, mutect2, varscan2
- CPS1 | c.2256C>T p.N752= | Silent (SNP) | VAF 108/268 reads (40%) | catalogued as rs770788292, COSV51818608; called by muse, mutect2, varscan2
- EFCAB6 | c.1266G>A p.P422= | Silent (SNP) | VAF 18/196 reads (9%) | catalogued as rs146730740, COSV53073821; called by muse, mutect2
- MROH2A | c.3801G>A p.P1267= | Silent (SNP) | VAF 132/296 reads (45%) | catalogued as rs764413682; called by muse, varscan2
- SLCO2A1 | chr3:133928578 C>T | 3'Flank (SNP) | VAF 169/476 reads (36%) | catalogued as rs752264285, COSV60485841; called by muse, mutect2, varscan2
